Somatic mutation profile of tumor specimen TCGA-24-2298-01A (aliquot TCGA-24-2298-01A-01W-0799-08) from TCGA case TCGA-24-2298, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.0 years (20,453 days).
Specimen TCGA-24-2298-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffd712cc-5f86-4dbb-8ccd-7f268035dca1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2298-11A (Solid Tissue Normal), aliquot TCGA-24-2298-11A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/174ec6f4-214f-4fc9-b005-eeefdf9d94a0

The open-access MAF lists 104 somatic variants for this specimen: 80 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 21, Nonsense Mutation 6, In Frame Del 3, Intron 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99328766; called by muse, mutect2, varscan2
- AC098582.1 | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 267/508 reads (53%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.528); catalogued as COSV99985708; called by muse, mutect2, varscan2
- AK3 | c.213G>C p.M71I | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.087); catalogued as COSV63346490, COSV63346867; called by muse, mutect2, varscan2
- AKAP6 | c.4422A>C p.Q1474H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV55218541; called by muse, mutect2, varscan2
- ALG11 | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV73000717; called by muse, mutect2, varscan2
- ARF5 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV50001329; called by muse, mutect2, varscan2
- ARFGAP2 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as rs1429166562, COSV54066471; called by muse, mutect2, varscan2
- ATP8A1 | c.1943A>G p.E648G | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV100046514; called by muse, mutect2
- BLMH | c.593G>C p.S198T | Missense Mutation (SNP) | VAF 66/85 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55585925; called by muse, varscan2
- CD109 | c.3265C>A p.L1089I | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54649548, COSV54656637, COSV99753902; called by muse, mutect2
- CD55 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.677); catalogued as COSV58577286; called by muse, mutect2, varscan2
- CD9 | c.65G>T p.W22L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV50530594; called by muse, mutect2, varscan2
- COL22A1 | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs200298766, COSV100278836, COSV57343458; called by muse, mutect2, varscan2
- COL6A6 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV62028692; called by muse, mutect2, varscan2
- CPLX4 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV55313983; called by muse, mutect2, varscan2
- CPXM1 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 35/76 reads (46%) | catalogued as COSV66045890; called by muse, mutect2, varscan2
- DCHS1 | c.6919C>A p.P2307T | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55037872; called by muse, mutect2, varscan2
- DENND4B | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100768763; called by muse, mutect2
- DNAH17 | c.3517G>C p.E1173Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); catalogued as COSV67757150; called by muse, mutect2, varscan2
- ELMOD2 | c.25T>A p.F9I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV60270702; called by muse, mutect2, varscan2
- EPHB3 | c.2217G>C p.L739F | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV57806995; called by muse, mutect2, varscan2
- FLAD1 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.289); catalogued as COSV52697784; called by muse, mutect2, varscan2
- FLI1 | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 125/253 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55645644; called by muse, mutect2, varscan2
- FMNL2 | c.2902T>G p.S968A | Missense Mutation (SNP) | VAF 136/392 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.316); catalogued as COSV99979981; called by muse, mutect2, varscan2
- FOXD4L3 | c.984A>T p.R328S | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.299); catalogued as COSV61551495; called by muse, mutect2, varscan2
- FUT8 | c.809C>T p.S270F (on ENST00000360689 / NM_001371534.1; = p.S107F on NM_004480.4) | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV61284750; called by muse, mutect2, varscan2
- GATAD2B | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 44/890 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.074); catalogued as COSV100897904; called by muse, mutect2
- GDPD5 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.301); catalogued as rs375711308; called by muse, varscan2
- GNPTAB | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 73/589 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1463358241, COSV100172089; called by muse, mutect2, varscan2
- GRIP1 | c.3062C>A p.A1021E (on ENST00000359742 / NM_001379345.1; = p.A969E on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/1212 reads (2%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99669927; called by muse, mutect2
- HTR6 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.084); catalogued as COSV53874127; called by muse, mutect2, varscan2
- INO80D | c.2998A>G p.I1000V | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.111); catalogued as rs750804655, COSV68959340; called by muse, mutect2, varscan2
- INO80D | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751185497, COSV68959342; called by muse, mutect2, varscan2
- IQCN | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV66575125; called by muse, mutect2, varscan2
- KIF19 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100739102; called by muse, mutect2
- KLHL31 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 112/188 reads (60%) | catalogued as COSV63881968; called by muse, mutect2, varscan2
- KLK7 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866275891, COSV58344999; called by muse, varscan2
- LMLN | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV54563216; called by muse, mutect2, varscan2
- LPAR5 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276462186, COSV61692697; called by muse, mutect2, varscan2
- MAPKBP1 | c.1953G>T p.K651N (on ENST00000456763 / NM_001128608.2; = p.K645N on NM_014994.3) | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99529738; called by muse, varscan2
- MAS1L | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV65809095; called by muse, mutect2, varscan2
- METTL15 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV57721023; called by muse, mutect2, varscan2
- MGAT4C | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs768547952, COSV100153072; called by muse, mutect2, varscan2
- MINDY2 | c.720A>T p.Q240H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100376461; called by muse, mutect2, varscan2
- MOBP | c.141T>G p.C47W | Missense Mutation (SNP) | VAF 90/132 reads (68%) | PolyPhen probably damaging (0.997); catalogued as COSV100215482, COSV60654314; called by muse, mutect2, varscan2
- MPDZ | c.1183A>T p.I395F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV100063153; called by muse, mutect2, varscan2
- MRTFA | c.1852C>G p.L618V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV62934228; called by muse, mutect2, varscan2
- MTERF4 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.829); catalogued as COSV54089666; called by muse, mutect2, varscan2
- MYH13 | c.3252G>T p.L1084F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV52833009, COSV52838817; called by muse, mutect2, varscan2
- MYO7A | c.3548C>A p.P1183H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV101289174; called by muse, mutect2, varscan2
- NCAPD3 | c.172T>A p.Y58N | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.441); catalogued as COSV55545573; called by muse, mutect2, varscan2
- PCDH9 | c.2910C>A p.D970E | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60562033; called by muse, mutect2, varscan2
- PIK3CG | c.2280T>A p.S760R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV63249804; called by muse, mutect2, varscan2
- PLA2G2D | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as rs1020702812, COSV100908031; called by muse, mutect2
- PMS1 | c.2027C>G p.P676R | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.626); catalogued as COSV59717389, COSV59720446; called by muse, mutect2, varscan2
- PRKCG | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV54729266; called by muse, mutect2, varscan2
- PRUNE2 | c.2404G>T p.A802S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV65043131; called by muse, mutect2, varscan2
- RPGRIP1 | c.3826A>G p.I1276V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV52851759; called by muse, mutect2, varscan2
- SALL3 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV73306168; called by muse, mutect2, varscan2
- SCN10A | c.3949G>T p.E1317* | Nonsense Mutation (SNP) | VAF 31/400 reads (8%) | catalogued as COSV101479439; called by muse, mutect2
- SEMA4F | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100336039; called by muse, mutect2
- SHE | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59072184; called by muse, mutect2, varscan2
- TAF4 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99434495; called by muse, mutect2, varscan2
- TET3 | c.2185T>C p.S729P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99996423; called by muse, mutect2, varscan2
- TMEM70 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV56488021; called by muse, mutect2, varscan2
- TNNT2 | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1416198683, CM116380, COSV99372351; called by muse, mutect2
- TRIP11 | c.3114G>T p.K1038N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50930836; called by muse, mutect2, varscan2
- TRIP12 | c.1325T>A p.L442Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52266633; called by muse, mutect2, varscan2
- TSHZ2 | c.2509A>G p.T837A | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV61589542; called by muse, mutect2, varscan2
- URB2 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 105/659 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.295); catalogued as COSV50981717, COSV99271383; called by muse, mutect2, varscan2
- USH2A | c.9025G>A p.A3009T | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100237420; called by muse, varscan2
- USP48 | c.2989G>T p.E997* | Nonsense Mutation (SNP) | VAF 37/335 reads (11%) | catalogued as COSV100379990; called by muse, mutect2, varscan2
- VAV3 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64069448; called by muse, mutect2, varscan2
- ZBTB17 | c.1904C>G p.T635S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as COSV65270452; called by muse, mutect2, varscan2
- ZNF329 | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV63772230; called by mutect2, varscan2
- CCDC24 | c.144_158del p.L49_A53del | In Frame Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, varscan2
- CDAN1 | c.1366A>G p.R456G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- FBXO43 | c.137_142del p.E46_A47del | In Frame Del (DEL) | VAF 44/356 reads (12%) | called by mutect2, pindel, varscan2
- IGLV4-60 | c.276_297delinsCGCT p.G93_T99delinsA | In Frame Del (DEL) | VAF 33/69 reads (48%) | called by pindel, varscan2*
- PLXNA3 | c.5325_5329del p.L1776Rfs*78 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel
- BMT2 | c.1050G>A p.E350= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV51777799; called by muse, mutect2, varscan2
- BPIFB1 | c.522C>T p.S174= | Silent (SNP) | VAF 11/374 reads (3%) | catalogued as COSV99487456; called by muse, mutect2
- CHRNA1 | c.774C>T p.Y258= (on ENST00000261007 / NM_001039523.3; = p.Y233= on NM_000079.4) | Silent (SNP) | VAF 36/201 reads (18%) | catalogued as COSV53683363; called by muse, mutect2, varscan2
- CYP4A11 | c.570C>T p.S190= | Silent (SNP) | VAF 78/338 reads (23%) | catalogued as rs1336754976, COSV60224117; called by muse, mutect2, varscan2
- DRAM1 | c.681C>A p.T227= | Silent (SNP) | VAF 58/305 reads (19%) | catalogued as COSV51598681; called by muse, mutect2, varscan2
- EIF4A3 | c.276C>T p.F92= | Silent (SNP) | VAF 24/392 reads (6%) | catalogued as rs1366491976, COSV53920778; called by muse, mutect2
- ESPL1 | c.2644C>T p.L882= | Silent (SNP) | VAF 29/285 reads (10%) | catalogued as COSV57760278; called by muse, mutect2, varscan2
- GNL1 | c.1653C>T p.D551= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs764776899, COSV64921179; called by muse, mutect2, varscan2
- GPR162 | c.873G>A p.V291= (on ENST00000311268 / NM_019858.2; = p.V7= on NM_014449.2) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99163811; called by muse, varscan2
- ITGA7 | c.1053C>T p.P351= (on ENST00000555728; = p.P307= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/91 reads (67%) | catalogued as rs775577770, COSV57696733, COSV99145156; called by muse, mutect2, varscan2
- OR2C1 | c.549C>T p.A183= | Silent (SNP) | VAF 38/484 reads (8%) | catalogued as COSV100514956; called by muse, mutect2
- PCDHB16 | c.657T>C p.S219= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs1306779075; called by mutect2, varscan2
- PLA2G4F | c.693C>G p.P231= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV51827606; called by mutect2, varscan2
- PRX | c.1944T>C p.A648= | Silent (SNP) | VAF 47/260 reads (18%) | catalogued as rs878961635; called by muse, varscan2
- RBM33 | c.1278A>G p.P426= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV100265560; called by muse, mutect2, varscan2
- SCN9A | c.3744T>C p.Y1248= (on ENST00000303354; = p.Y1237= on NM_002977.3) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV57613966; called by mutect2, varscan2
- SLC39A12 | c.123C>T p.G41= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as COSV101070077; called by muse, mutect2
- SRP54 | c.1224A>G p.R408= | Silent (SNP) | VAF 62/266 reads (23%) | catalogued as COSV53740417; called by muse, varscan2
- TCTE1 | c.585G>A p.Q195= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101025479; called by muse, mutect2, varscan2
- ZNF608 | c.633G>A p.R211= | Silent (SNP) | VAF 47/211 reads (22%) | catalogued as COSV100101966; called by muse, mutect2, varscan2
- ZSCAN20 | c.2286A>G p.G762= | Silent (SNP) | VAF 18/414 reads (4%) | catalogued as COSV100792662; called by muse, mutect2
- EEF1B2 | c.331-138C>T | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99261111; called by muse, mutect2, varscan2
- SNORD114-22 | n.66G>A | RNA (SNP) | VAF 60/242 reads (25%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7221A>T | Intron (SNP) | VAF 17/371 reads (5%) | called by muse, mutect2
